TARGET case TARGET-30-PARFWB — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/af7249ba-9ef1-57e3-a685-47c7296faf7b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 1,836 days (5.0 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C47.3; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of thorax; Classification of tumor: primary; Age at diagnosis: 4.3 years (1,555 days); Year of diagnosis: 2007; Days to last follow up: 1,836 days (5.0 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Necrosis percent: 40; Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ADVL0921.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL1021.

Follow-up (2 entries)
- Days to follow up: 1,105 days (3.0 years); Progression or recurrence anatomic site: Bone, NOS; Days to first event: 1,105 days (3.0 years); First event: Relapse.
- Days to follow up: 1,836 days (5.0 years); Year of follow up: 2012.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PARFWB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PARFWB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1836
- Protocol: ANBL00B1, ADVL0921, ANBL1021
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Peripheral nerves and Autonomic nervous system of thorax Peripheral nerves and Autonomic nervous system of (see list under C47): . Axilla . Chest . chest wall . thoracic wall . infraclavicular region . scapular region Intercostal nerve
- Percent Tumor v/s Stroma: 90/10
- Site of Relapse: Bone
